Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7901, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7901-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

ID	Case ID	Gross Description	Microscopic Description
[REDACTED]	[REDACTED]	Stomach and lower part of the esophagus. In the cardia part of the stomach -- plate-like tumor of 8 x 6 cm in size. Tumor spreads to the esophagus, invade into the fat tissue. Cardia-esophagial lymph nodes are rosy colored, dense. Omentum is hyperemic. Separately taken lymph node is black colored, soft.	Adenocarcinoma (cardia-esophageal junction); G2; adjacent fatty tissue invasion; tumor spreads into the wall adjacent lymph node. Fifteen lymph nodes are examined, two lymph nodes demonstrate metastases. Omentum and surgical margins are tumor free.

[page 2 of 3]
Diagnosis Details	Comments
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:	

[page 3 of 3]
Formatted Path Report		Date of Procurement	Laterality
STOMACH TISSUE CHECKLIST Specimen type: Total gastrectomy Tumor site: Gastroesophageal junction Tumor size: 6 x 0 x 8 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 2/15 positive for metastasis (Greater and lesser omentum 2/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None			

Source: NCI Genomic Data Commons file ead84652-2d98-477e-af97-954beb925151 (TCGA-BR-7901.D3B5AD77-4461-4BD9-8791-09D03E212A51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).